Gene-level copy-number profile of tumor specimen ALCH-B3ZT-TTP1-A from ALCHEMIST case ALCH-B3ZT, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 73.4 years (26,814 days).
Specimen ALCH-B3ZT-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file fd27f52b-7ec4-4d08-a919-f5455a7635a3.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B3ZT-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,725 have no estimate.
https://portal.gdc.cancer.gov/files/761cc9c8-b668-4b11-8b87-376cebb5cad0

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 91; copy number 1: 6,214; copy number 2: 50,441; copy number 3: 1,045; copy number 4: 1,004; copy number 5: 26; copy number 6: 5; copy number 7: 9; copy number 8: 20; copy number 9: 31; copy number 10: 10; copy number 31: 2.

Homozygous deletions (total copy number 0; autosomes only): 68 genes in 26 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:32,717,734–32,725,237, 1 gene: AC114489.1.
- chr1:33,162,851–33,166,298, 1 gene (within-gene range 0–2): AL662907.2.
- chr1:62,211,557–62,211,666, 1 gene (within-gene range 0–2): Y_RNA.
- chr2:130,129,621–130,139,417, 1 gene (within-gene range 0–3): MED15P9.
- chr2:130,151,392–130,190,729, 2 genes: SMPD4, MZT2B.
- chr2:238,138,668–238,168,900, 3 genes: KLHL30, KLHL30-AS1, ERFE.
- chr3:5,099,627–5,099,861, 1 gene: AC090955.1.
- chr3:181,866,351–181,867,154, 1 gene: AC007547.1.
- chr4:112,685,055–112,685,503, 1 gene: OSTCP4.
- chr4:112,693,459–112,693,792, 1 gene (within-gene range 0–2): WRBP1.
- chr7:56,875,385–56,882,146, 1 gene: AC118758.1.
- chr9:125,417,305–125,417,586, 1 gene: Metazoa_SRP.
- chr9:135,907,812–135,916,126, 1 gene: AL355574.1.
- chr10:35,250,959–35,251,052, 1 gene (within-gene range 0–2): RNU6-1167P.
- chr11:57,450,183–57,452,022, 2 genes: RNA5SP341, RN7SKP259.
- chr15:25,170,723–25,211,877, 23 genes (within-gene range 0–1): SNORD115-1, SNORD115-2, SNORD115-3, SNORD115-4, SNORD115-5, SNORD115-6, SNORD115-7, SNORD115-8, SNORD115-9, SNORD115-10, SNORD115-11, SNORD115-12, SNORD115-13, SNORD115-14, SNORD115-15, SNORD115-16, SNORD115-17, SNORD115-18, SNORD115-19, SNORD115-20, SNORD115-21, SNORD115-22, SNORD115-23.
- chr16:58,025,754–58,083,168, 2 genes: MMP15, Y_RNA.
- chr16:81,022,316–81,096,284, 1 gene (within-gene range 0–2): AC092718.8.
- chr16:81,053,497–81,096,296, 5 genes (within-gene range 0–2): C16orf46, AC092718.3, AC092718.5, AC092718.6, AC092718.1.
- chr17:4,364,164–4,364,453, 1 gene (within-gene range 0–2): RN7SL774P.
- chr19:2,163,933–2,235,926, 3 genes (within-gene range 0–2): DOT1L, AC004490.1, MIR6789.
- chr19:8,363,289–8,404,434, 4 genes (within-gene range 0–2): ANGPTL4, RAB11B-AS1, MIR4999, RAB11B.
- chr19:16,134,028–16,173,525, 2 genes (within-gene range 0–2): HSH2D, CIB3.
- chr19:35,106,510–35,143,109, 6 genes (within-gene range 0–2): AC020907.6, FXYD3, MIR6887, LGI4, AC020907.5, FXYD1.
- chr20:62,952,707–62,969,585, 1 gene: SLC17A9.
- chr22:18,733,914–18,757,906, 1 gene: FAM230E.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 101 genes in 12 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:9,425,094–9,440,564, 2 genes, copy number 5: LINC02606, RNA5SP40.
- chr1:244,835,616–244,865,272, 3 genes, copy number 5: COX20, HNRNPU, BX323046.1.
- chr2:242,175,181–242,175,634, 1 gene, copy number 8: RPL23AP88.
- chr5:1,544,107–1,634,005, 6 genes, copy number 5: AC091849.2, SDHAP3, AC026412.3, AC091849.1, AC026412.1, AC026412.2.
- chr8:7,442,684–7,463,674, 1 gene, copy number 5: SPAG11B.
- chr8:140,657,900–141,002,216, 4 genes, copy number 5: PTK2, MIR151A, AC105235.1, RNA5SP278.
- chr12:57,591,174–60,419,293, 61 genes, copy number 5–9 (broad region; genes not listed).
- chr12:68,746,125–68,971,570, 10 genes, copy number 10: SLC35E3, AC025423.3, MDM2, AC025423.1, AC025423.4, AC025423.2, CPM, RNU7-4P, AC025423.5, PRELID2P1.
- chr12:69,239,569–69,285,485, 3 genes, copy number 6: CPSF6, MIR1279, C1GALT1P1.
- chr17:83,220,527–83,240,804, 2 genes, copy number 6: AC139099.1, RPL23AP87.
- chr19:58,573,503–58,605,223, 4 genes, copy number 5 (within-gene range 2–7): CENPBD1P1, AC016629.3, AC016629.1, AC016629.2.
- chr22:18,846,811–18,894,407, 4 genes, copy number 7–31: AC008132.1, BCRP7, FAM230F, AC008103.1.

Autosomal genes at a single copy (total copy number 1): 3,414. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
